Somatic mutation profile of tumor specimen TARGET-10-PARNDB-09A (aliquot TARGET-10-PARNDB-09A-01D) from TARGET case TARGET-10-PARNDB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,701 days).
Specimen TARGET-10-PARNDB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bce515d3-0823-42de-9ddd-a375232bc241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNDB-10A (Blood Derived Normal), aliquot TARGET-10-PARNDB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53f618fb-76ce-499c-a8fc-f889d4ee3f46

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.6079C>T p.R2027* | Nonsense Mutation (SNP) | VAF 40/75 reads (53%) | catalogued as rs886040995, CM060921, COSV71109635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDK20 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs565837414, COSV57482985; called by muse, mutect2, varscan2
- CYP46A1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs769217801; called by muse, mutect2, varscan2
- GUCY2F | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TFB1M | c.990A>C p.K330N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TRRAP | c.5505C>T p.Y1835= (on ENST00000359863 / NM_001244580.1; = p.Y1817= on NM_003496.3) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs199909227; called by muse, mutect2, varscan2
- ZNF517 | c.34-36C>T | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
